TCGA case TCGA-A6-5667 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28d03569-8717-40da-8989-70baf2b18f9f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 40.4 years (14,756 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 887 days (2.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 48; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 223 days; Number of cycles: 12; Treatment dose: 8,674 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 225 days; Number of cycles: 12; Treatment dose: 52,044 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 223 days; Number of cycles: 12; Treatment dose: 925 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 160 days; Number of cycles: 8; Treatment dose: 1,026 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 320 days; Disease response: Tumor Free.
- Days to follow up: 887 days (2.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 36.3 ng/mL.
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 175 cm; BMI: 24.8.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-5667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-A6-5667-01A-01-BS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-A6-5667-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-5667-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-5667-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.7; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 36.3; Lymphovascular invasion indicator: Yes; Microsatellite instability: No; Loci tested count: 4; Loci abnormal count: 0; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 4: Regimen number: 1; Pharmaceutical therapy drug name: 5FU.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 887 days; disease-specific survival: no event (censored), 887 days; disease-free interval: no event (censored), 887 days; progression-free interval: no event (censored), 887 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-5667-01A-21D-1717-01): tumor purity 0.69, ploidy 3.2, whole-genome doublings 1.
